Somatic mutation profile of tumor specimen TCGA-43-A475-01A (aliquot TCGA-43-A475-01A-11D-A24D-08) from TCGA case TCGA-43-A475, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.6 years (24,680 days).
Specimen TCGA-43-A475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bf6712f-b9e2-4b1a-b47d-faf88cf5c815.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-A475-10A (Blood Derived Normal), aliquot TCGA-43-A475-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a55a84ff-6b54-43e5-819e-41a61aaefc21

The open-access MAF lists 272 somatic variants for this specimen: 205 protein-altering or splice-affecting, 59 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 59, Nonsense Mutation 10, Frame Shift Del 9, 3'UTR 4, Splice Region 3, RNA 2, Splice Site 2, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.181T>C p.W61R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV100750848; called by muse, mutect2, varscan2
- ABCC12 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100252806; called by muse, mutect2, varscan2
- ABCG8 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757824090, COSV99699915; called by muse, mutect2, varscan2
- ACADL | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as rs1029638650, COSV99284828; called by muse, mutect2, varscan2
- ACSM2A | c.1262G>T p.G421V (on ENST00000219054; = p.G342V on NM_001308169.2) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs768002944, COSV99525347; called by muse, mutect2, varscan2
- ACTL6B | c.549C>A p.Y183* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99355595; called by muse, mutect2, varscan2
- ADAMTS12 | c.2135A>T p.E712V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100711125; called by muse, mutect2, varscan2
- ADGRG4 | c.2152G>T p.D718Y | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99795764; called by muse, mutect2, varscan2
- AKAP13 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100773961; called by muse, mutect2, varscan2
- ANKLE2 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514196; called by muse, mutect2
- ANO6 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100263380; called by muse, mutect2, varscan2
- ARHGAP15 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV54476898, COSV99711405; called by muse, mutect2, varscan2
- ARHGAP6 | c.1275C>A p.G425= | Splice Region (SNP) | VAF 34/319 reads (11%) | catalogued as COSV57301430; called by muse, mutect2, varscan2
- ATP10D | c.1400G>T p.R467M | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV99905718; called by muse, mutect2, varscan2
- BRAF | c.712-1G>T p.X238_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56286094, COSV99963113; called by muse, mutect2
- BRCA2 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1170876773, COSV101204325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1355958794, COSV58670301; called by muse, mutect2, varscan2
- BRWD3 | c.3223C>A p.P1075T | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV100956180; called by muse, mutect2, varscan2
- C6orf136 | c.659G>A p.R220H (on ENST00000376473 / NM_001109938.3; = p.R86H on NM_145029.4) | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs1385471304, COSV53314614; called by muse, mutect2, varscan2
- CACNA1C | c.1215C>T p.S405= | Splice Region (SNP) | VAF 26/142 reads (18%) | catalogued as rs751480224, COSV100216745; called by mutect2, varscan2
- CCDC151 | c.717C>G p.D239E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100710555; called by muse, mutect2, varscan2
- CCDC85A | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV101339479; called by muse, varscan2
- CCR6 | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100551107; called by muse, mutect2, varscan2
- CD200R1L | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs377219496; called by muse, mutect2
- CEACAM8 | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs764085069, COSV99747664; called by muse, mutect2, varscan2
- CHD7 | c.4775G>T p.R1592L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV101418278, COSV71114274; called by muse, mutect2, varscan2
- CHML | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 105/413 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as rs1253592275, COSV100087496; called by muse, mutect2, varscan2
- CLCN4 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV101073874; called by muse, mutect2, varscan2
- CLPTM1L | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.296); catalogued as rs761764913, COSV100307112, COSV100307365; called by muse, mutect2, varscan2
- COL4A5 | c.2914C>G p.P972A | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as COSV100088056; called by muse, mutect2
- COL6A6 | c.4058G>T p.G1353V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100650362; called by muse, mutect2, varscan2
- CUBN | c.4325C>A p.S1442* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100912882; called by muse, mutect2, varscan2
- DCAF8L1 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | catalogued as COSV101491476; called by muse, mutect2, varscan2
- DDX53 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100028966; called by muse, mutect2, varscan2
- DGLUCY | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs150428305; called by muse, mutect2, varscan2
- DLGAP1 | c.1759A>G p.S587G | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs774346471, COSV100231736; called by muse, mutect2, varscan2
- DNA2 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs529850423, COSV100622632, COSV64428646; called by muse, mutect2, varscan2
- DNAH3 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1013012929, COSV54511759, COSV99770890; called by muse, mutect2, varscan2
- DOCK7 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52022370, COSV99224806; called by muse, mutect2, varscan2
- ENPP1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100719572; called by muse, mutect2, varscan2
- EP300 | c.4154G>A p.C1385Y | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54325300, COSV54328894; called by muse, mutect2
- ESRRG | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.103); catalogued as COSV100753176; called by muse, mutect2, varscan2
- F8 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CX063745, COSV100811608; called by muse, mutect2, varscan2
- F8 | c.98G>C p.W33S | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM031978; called by muse, mutect2, varscan2
- FAM120C | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs201814207, COSV100070171; called by muse, mutect2, varscan2
- FAM124B | c.269A>T p.Q90L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99706365; called by muse, mutect2, varscan2
- FAM135B | c.2800G>T p.V934L | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs774190593, COSV99424759; called by muse, mutect2, varscan2
- FAM193B | c.1284G>C p.E428D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.945); catalogued as COSV100286637; called by muse, mutect2, varscan2
- FAM47A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.033); catalogued as COSV100649942; called by muse, mutect2, varscan2
- FAM53B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs368959802; called by muse, mutect2, varscan2
- FAM71B | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs775977622, COSV100262153; called by muse, mutect2, varscan2
- FATE1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as COSV100948159; called by muse, mutect2, varscan2
- FBXL7 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV100308972, COSV100309997; called by muse, mutect2, varscan2
- FBXO28 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.1); catalogued as COSV100837453; called by muse, mutect2, varscan2
- FLNB | c.7614C>G p.S2538R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV99913576; called by muse, varscan2
- FLRT2 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100420529; called by muse, mutect2, varscan2
- FSHR | c.1029C>G p.D343E | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs760439697, COSV100437358, COSV58620266; called by muse, mutect2, varscan2
- GABRG2 | c.1376G>T p.C459F (on ENST00000361925 / NM_001375343.1; = p.C419F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729735; called by muse, mutect2, varscan2
- GALNT15 | c.1633C>A p.L545M | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100327716; called by muse, mutect2, varscan2
- GAREM1 | c.1840A>T p.S614C (on ENST00000269209 / NM_001242409.2; = p.S613C on NM_022751.3) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV99330816; called by muse, mutect2, varscan2
- GJA1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM086828, COSV99247059; called by muse, mutect2, varscan2
- GPR180 | c.762G>C p.Q254H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as COSV100979055; called by muse, mutect2, varscan2
- GPRASP1 | c.2282C>G p.S761* | Nonsense Mutation (SNP) | VAF 23/200 reads (12%) | catalogued as COSV100851013; called by muse, mutect2, varscan2
- GTF2E1 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99381996; called by muse, mutect2, varscan2
- GTF3C1 | c.4235C>A p.T1412N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV100649491; called by muse, mutect2, varscan2
- HEPH | c.2980G>T p.G994C (on ENST00000343002; = p.G727C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57959948; called by muse, mutect2, varscan2
- HGS | c.1186T>G p.F396V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100230555; called by muse, mutect2
- HUWE1 | c.8788G>A p.D2930N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99472770; called by muse, mutect2
- IGKV2-24 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs762315806; called by muse, mutect2, varscan2
- IL13RA1 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100861561; called by muse, mutect2, varscan2
- IL7R | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV100286333; called by muse, mutect2, varscan2
- IPCEF1 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99499871; called by muse, mutect2, varscan2
- IRS4 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100929600; called by muse, mutect2, varscan2
- ISM2 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV99376703; called by muse, mutect2, varscan2
- ITGB1 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs372397463; called by muse, mutect2, varscan2
- ITPKB | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as COSV55260828, COSV55261266; called by muse, mutect2, varscan2
- KANK2 | c.1733C>T p.S578L (on ENST00000586659 / NM_001379562.1; = p.S586L on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100763238; called by muse, mutect2
- KATNIP | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758292991, COSV99851327; called by muse, mutect2, varscan2
- KIF21B | c.2591G>C p.R864P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV100144655, COSV100144901; called by muse, mutect2, varscan2
- LRP1B | c.9944C>T p.S3315F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101257792, COSV67255758; called by muse, mutect2, varscan2
- MAGEB1 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100975011, COSV66775987; called by muse, mutect2, varscan2
- MAGT1 | c.951G>A p.M317I (on ENST00000618282 / NM_001367916.1; = p.M349I on NM_032121.5) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100800263; called by muse, mutect2, varscan2
- MAPKBP1 | c.2648A>C p.Q883P (on ENST00000456763 / NM_001128608.2; = p.Q877P on NM_014994.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV99529670; called by muse, mutect2, varscan2
- MCM4 | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs752922408, COSV100031597; called by muse, mutect2, varscan2
- MEPE | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779559543, COSV63074282; called by muse, mutect2, varscan2
- MID2 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV99464852; called by muse, mutect2, varscan2
- MIS18BP1 | c.1870G>C p.D624H | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173054; called by muse, mutect2
- MLXIPL | c.2365del p.A789Qfs*28 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | catalogued as COSV57670886; called by mutect2, pindel, varscan2
- MROH2B | c.2605C>A p.L869I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101270732, COSV68184845; called by muse, mutect2, varscan2
- MTIF3 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV101137511; called by muse, mutect2
- MXRA5 | c.4114G>T p.V1372L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99477410; called by muse, mutect2, varscan2
- MYF6 | c.406A>T p.S136C | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99952857; called by muse, mutect2, varscan2
- MYO7B | c.5301C>G p.C1767W | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268239; called by muse, mutect2, varscan2
- NBEA | c.8102G>T p.S2701I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100081287; called by muse, mutect2, varscan2
- NCAM2 | c.216A>T p.E72D | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV99523445; called by muse, mutect2, varscan2
- NCAPD2 | c.3461A>G p.N1154S | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs199672478, COSV100217269; called by muse, mutect2, varscan2
- NCKIPSD | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV53660802, COSV99584013; called by muse, mutect2, varscan2
- NCOR2 | c.2674A>T p.K892* | Nonsense Mutation (SNP) | VAF 6/105 reads (6%) | catalogued as COSV100657450; called by muse, mutect2
- NETO1 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV100198926; called by muse, mutect2, varscan2
- NFE2L3 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99283789; called by muse, mutect2, varscan2
- NGLY1 | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99770609; called by muse, mutect2, varscan2
- NKAPL | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100642530, COSV59199486; called by muse, mutect2, varscan2
- NKRF | c.1838A>C p.Y613S | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100441725; called by muse, mutect2
- NLRP12 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100145373; called by muse, mutect2, varscan2
- NLRP13 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61622513; called by muse, mutect2, varscan2
- NPR1 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100902038; called by muse, mutect2, varscan2
- NRDE2 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100583516; called by muse, mutect2, varscan2
- NUP210L | c.4591A>T p.R1531W | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99668290; called by muse, mutect2, varscan2
- NXT2 | c.359C>A p.S120Y (on ENST00000372106 / NM_001242617.2; = p.S175Y on NM_018698.5) | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV54297645, COSV99484156; called by muse, mutect2, varscan2
- OFD1 | c.2539G>T p.G847W | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406959; called by muse, mutect2, varscan2
- OPHN1 | c.996G>T p.R332S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100830537; called by muse, mutect2, varscan2
- OR10G8 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs371712678, COSV101461846; called by muse, mutect2, varscan2
- OR2L3 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 100/418 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100741986; called by muse, mutect2, varscan2
- OR4D5 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100190012, COSV58309649; called by muse, mutect2, varscan2
- OR4K5 | c.190G>T p.G64* | Nonsense Mutation (SNP) | VAF 76/605 reads (13%) | catalogued as COSV100262414, COSV100262651; called by muse, mutect2, varscan2
- OR4N5 | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100374119; called by muse, mutect2, varscan2
- OR7A17 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100541626; called by muse, mutect2, varscan2
- OTP | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100119834; called by muse, mutect2, varscan2
- OXR1 | c.2326G>C p.G776R (on ENST00000442977 / NM_001198532.1; = p.G748R on NM_018002.3) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861045; called by muse, mutect2, varscan2
- P2RY10 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409170; called by muse, mutect2, varscan2
- PABPC5 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442176; called by muse, mutect2, varscan2
- PABPC5 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100442437; called by muse, mutect2, varscan2
- PDZD2 | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99225407; called by muse, mutect2, varscan2
- PHKG1 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV99305157; called by muse, mutect2, varscan2
- PHTF2 | c.1274A>C p.D425A (on ENST00000248550 / NM_001366089.1; = p.D387A on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99301874; called by muse, mutect2, varscan2
- PLEKHA4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54364880; called by muse, varscan2
- PLSCR3 | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100247943; called by muse, mutect2, varscan2
- PPP1R9A | c.3137A>C p.K1046T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99196003; called by muse, mutect2, varscan2
- PQBP1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV54430596; called by muse, mutect2
- PRIM1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100590410; called by muse, mutect2, varscan2
- PRUNE2 | c.2400G>C p.W800C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040698; called by muse, mutect2, varscan2
- PSD | c.1552A>T p.S518C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99192865; called by muse, mutect2, varscan2
- PSMA4 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs754693970, COSV50385177; called by muse, mutect2, varscan2
- PTPRM | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194899995, COSV100157893; called by muse, mutect2, varscan2
- R3HDM2 | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100234622; called by muse, mutect2, varscan2
- RAB42 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1241234070, COSV100866086; called by muse, mutect2, varscan2
- RORB | c.630C>A p.N210K (on ENST00000396204 / NM_001365023.1; = p.N199K on NM_006914.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV100974367; called by muse, mutect2, varscan2
- RSPH14 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99320866; called by muse, mutect2, varscan2
- RTKN2 | c.1256T>G p.F419C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100189449; called by muse, mutect2, varscan2
- RTL9 | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1205299045, COSV101511710; called by muse, mutect2, varscan2
- SCN4A | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs867372759, COSV101438520; called by muse, mutect2, varscan2
- SEMA6D | c.3058C>T p.H1020Y (on ENST00000316364 / NM_153618.2; = p.H958Y on NM_020858.2) | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV100317139; called by muse, mutect2, varscan2
- SERPINB4 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100345782; called by muse, mutect2, varscan2
- SGCZ | c.547+1G>A p.X183_splice | Splice Site (SNP) | VAF 30/85 reads (35%) | catalogued as COSV101170272; called by muse, mutect2, varscan2
- SH2D3C | c.1601C>A p.P534H (on ENST00000314830 / NM_170600.3; = p.P377H on NM_005489.4) | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100137017; called by muse, mutect2, varscan2
- SHROOM4 | c.1910C>T p.T637I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99173638; called by muse, mutect2, varscan2
- SIPA1L1 | c.3522G>T p.G1174= | Splice Region (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100665648; called by muse, mutect2, varscan2
- SLC12A1 | c.2153T>C p.V718A | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.103); catalogued as COSV101118874; called by muse, mutect2, varscan2
- SLC6A2 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.034); catalogued as rs1466256660, COSV99574047; called by muse, mutect2
- SLCO1B1 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918611; called by muse, mutect2, varscan2
- SNTG1 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV52451088, COSV52476532; called by muse, mutect2, varscan2
- SOX14 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048238; called by muse, mutect2, varscan2
- SPATA4 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV54588841, COSV99709006; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | PolyPhen benign (0.028); catalogued as COSV100231472; called by muse, varscan2
- STRBP | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV100724226; called by muse, mutect2, varscan2
- SUN1 | c.2450A>C p.H817P (on ENST00000405266 / NM_001367651.1; = p.H697P on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768701; called by muse, mutect2, varscan2
- SUV39H1 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100551791; called by muse, mutect2, varscan2
- SYT11 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100851317; called by muse, mutect2, varscan2
- TAB3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99916344; called by muse, mutect2, varscan2
- TAF6L | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99585252; called by muse, mutect2, varscan2
- TBC1D8B | c.604T>A p.W202R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99344525; called by muse, mutect2
- TBX4 | c.1456G>T p.G486W | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV53607018; called by muse, mutect2, varscan2
- TCEAL1 | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV101010126; called by muse, mutect2, varscan2
- TENM1 | c.2753T>A p.I918N | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100950273; called by muse, mutect2, varscan2
- TENM1 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64436001, COSV64442957; called by muse, mutect2, varscan2
- TGS1 | c.2132C>A p.T711K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV99485454; called by muse, varscan2
- THSD7A | c.3019G>T p.D1007Y | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101448759, COSV70260281; called by muse, mutect2, varscan2
- TIPRL | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100893291, COSV63207628; called by muse, mutect2, varscan2
- TLR6 | c.1129_1132del p.V377Nfs*12 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs1317174148; called by pindel, varscan2
- TMEM200C | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.346); catalogued as COSV101274842; called by muse, mutect2, varscan2
- TMEM38B | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 14/146 reads (10%) | catalogued as COSV101016390; called by muse, mutect2
- TNN | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99512170; called by muse, mutect2, varscan2
- TNNI2 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53290175, COSV99425500; called by muse, mutect2, varscan2
- TRIM60 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100594043; called by muse, mutect2, varscan2
- TTN | c.34531G>A p.A11511T (on ENST00000591111; = p.A10584T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/200 reads (33%) | PolyPhen benign (0); catalogued as rs1342281244, COSV100617470; called by muse, mutect2, varscan2
- TUT7 | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.187); catalogued as COSV99463163; called by muse, mutect2, varscan2
- UGT2B10 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1330652399, COSV55318779, COSV55318917; called by muse, mutect2, varscan2
- USP51 | c.860T>G p.M287R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV101540669; called by muse, mutect2, varscan2
- VEGFD | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV99938449; called by muse, mutect2, varscan2
- VPS13D | c.171A>T p.K57N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV100693187; called by muse, mutect2, varscan2
- VSIG4 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV101038186; called by muse, mutect2, varscan2
- WSCD1 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV100496644; called by muse, mutect2
- XIAP | c.1016T>A p.I339K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100848889, COSV63022080; called by muse, mutect2, varscan2
- ZBED1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100585639; called by muse, mutect2, varscan2
- ZMYM3 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.708); catalogued as COSV100077999; called by muse, mutect2, varscan2
- ZNF202 | c.1768G>C p.V590L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV100279068; called by muse, mutect2, varscan2
- ZNF334 | c.872G>T p.R291I | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100749108; called by muse, mutect2, varscan2
- ZNF479 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as COSV100482792, COSV58641012; called by muse, mutect2, varscan2
- ZNF516 | c.856A>T p.K286* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV101487302; called by muse, mutect2, varscan2
- ZNF627 | c.76A>T p.K26* | Nonsense Mutation (SNP) | VAF 57/142 reads (40%) | catalogued as COSV100741488; called by muse, mutect2, varscan2
- DUSP14 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F8 | c.5266del p.E1756Nfs*16 | Frame Shift Del (DEL) | VAF 18/173 reads (10%) | called by mutect2, pindel, varscan2
- FMN1 | c.3137del p.K1046Rfs*17 (on ENST00000616417 / NM_001277313.2; = p.K823Rfs*17 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 41/174 reads (24%) | called by mutect2, pindel, varscan2
- HRNR | c.7087C>A p.H2363N | Missense Mutation (SNP) | VAF 69/2462 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2
- IL3RA | c.654_656del p.N218del | In Frame Del (DEL) | VAF 29/138 reads (21%) | called by pindel, varscan2
- LAMB1 | c.3303del p.Q1102Sfs*87 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- LHX1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2
- PCDHGB2 | c.288dup p.G97Rfs*15 | Frame Shift Ins (INS) | VAF 44/177 reads (25%) | called by mutect2, pindel, varscan2
- PIGK | c.376del p.V126* | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, varscan2
- PLXNA3 | c.3988del p.L1330Cfs*99 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM51 | c.968del p.G323Efs*49 | Frame Shift Del (DEL) | VAF 31/128 reads (24%) | called by mutect2, pindel, varscan2
- UBE2NL | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ZNF215 | c.93del p.W31Cfs*27 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12345C>A p.T4115= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV101446991; called by muse, mutect2, varscan2
- ABI1 | c.420T>C p.P140= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100697922; called by muse, mutect2, varscan2
- ADGRG6 | c.2745C>T p.F915= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV99747537; called by muse, mutect2, varscan2
- BEND2 | c.1341C>T p.S447= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs776879324, COSV66215062; called by muse, mutect2
- BRINP3 | c.453G>C p.V151= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100818964, COSV66529978; called by muse, mutect2, varscan2
- CD101 | c.1800T>C p.T600= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV99869781; called by muse, mutect2, varscan2
- DCAF12L1 | c.759C>T p.I253= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100948338; called by muse, mutect2, varscan2
- DMXL1 | c.819A>G p.P273= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100224222; called by muse, mutect2, varscan2
- DOCK11 | c.642A>T p.S214= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV99354060; called by muse, mutect2, varscan2
- EME2 | c.495C>T p.H165= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as COSV99169251; called by muse, mutect2, varscan2
- FAM120B | c.424C>A p.R142= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV99379477; called by muse, mutect2
- FOXI2 | c.612C>G p.A204= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV59094384; called by muse, mutect2
- FSD1 | c.396A>G p.L132= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs751114504, COSV99696826; called by muse, mutect2, varscan2
- GPR148 | c.612A>T p.P204= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV99998608; called by muse, mutect2, varscan2
- GPR156 | c.2208C>T p.S736= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV100251427; called by muse, mutect2, varscan2
- H3C7 | c.117C>A p.P39= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV99769134; called by muse, mutect2, varscan2
- IL1RAPL1 | c.558G>A p.R186= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100147641; called by muse, mutect2, varscan2
- KDM5C | c.972A>T p.S324= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100949259; called by muse, mutect2, varscan2
- KIF4B | c.2793G>C p.V931= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV101469304; called by muse, mutect2, varscan2
- KRTAP13-2 | c.246C>T p.R82= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1383849702, COSV101299642; called by muse, mutect2, varscan2
- KRTAP19-5 | c.63G>T p.L21= | Silent (SNP) | VAF 31/224 reads (14%) | catalogued as COSV61858276; called by muse, mutect2, varscan2
- LPA | c.6081A>T p.S2027= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV100307176; called by muse, mutect2, varscan2
- MAP7D3 | c.915A>G p.A305= | Silent (SNP) | VAF 14/466 reads (3%) | catalogued as COSV100286405; called by muse, mutect2
- MBD4 | c.750T>C p.C250= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as COSV99959440; called by muse, mutect2, varscan2
- MEDAG | c.102G>A p.L34= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- MGAM | c.792T>C p.Y264= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV101516447; called by muse, mutect2, varscan2
- MRI1 | c.885C>T p.I295= (on ENST00000040663 / NM_001031727.4; = p.I248= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV50003996, COSV99237544; called by muse, mutect2, varscan2
- MYH2 | c.1680G>T p.L560= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV99820356; called by muse, mutect2, varscan2
- MYH4 | c.5157T>G p.L1719= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99701493; called by muse, mutect2, varscan2
- NEXMIF | c.1038C>A p.P346= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV99281023; called by muse, mutect2, varscan2
- NOL4 | c.1809A>T p.P603= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV52344314, COSV52356396, COSV99307933; called by muse, mutect2, varscan2
- OBSCN | c.15360G>A p.L5120= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99479965; called by muse, mutect2
- OR10G8 | c.135G>T p.L45= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV101461845; called by muse, mutect2, varscan2
- OR1S2 | c.261T>A p.I87= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as COSV100224244; called by muse, mutect2, varscan2
- OR4K13 | c.666A>T p.I222= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV100237764; called by muse, mutect2, varscan2
- OR5D16 | c.849G>T p.V283= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV101004002, COSV65722367; called by muse, mutect2, varscan2
- PCDHA6 | c.2256G>A p.Q752= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV100971545; called by muse, mutect2, varscan2
- PCLO | c.807T>C p.H269= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100433645; called by muse, mutect2, varscan2
- PHF6 | c.321T>C p.C107= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100136602; called by mutect2, varscan2
- PLOD3 | c.1542G>T p.R514= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99778089; called by muse, mutect2, varscan2
- PON3 | c.558C>T p.T186= | Silent (SNP) | VAF 51/207 reads (25%) | catalogued as COSV99672551; called by muse, mutect2, varscan2
- PRIM1 | c.912G>T p.R304= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100590409; called by muse, mutect2, varscan2
- RAN | c.255T>C p.C85= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99619780; called by muse, mutect2, varscan2
- RER1 | c.543G>A p.K181= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV99992130; called by muse, mutect2, varscan2
- RXFP3 | c.300G>T p.L100= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100347596; called by muse, mutect2, varscan2
- RYR2 | c.12432C>A p.R4144= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV100770983; called by muse, mutect2, varscan2
- SH3BP4 | c.2574G>T p.R858= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100749204; called by muse, mutect2, varscan2
- SKAP1 | c.186C>T p.D62= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs763137474, COSV100411931; called by muse, mutect2, varscan2
- SNRPN | c.514C>A p.R172= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100578297, COSV57599968; called by muse, mutect2, varscan2
- SPICE1 | c.1818C>G p.V606= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV99871469; called by muse, mutect2, varscan2
- TTN | c.68232T>C p.T22744= (on ENST00000591111; = p.T15320= on NM_003319.4) | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60468623; called by muse, mutect2, varscan2
- UGT3A1 | c.162T>A p.T54= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99954892; called by muse, mutect2, varscan2
- USH2A | c.7026C>A p.S2342= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as COSV100236732; called by muse, mutect2, varscan2
- USP9X | c.3843C>T p.D1281= | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as rs768506015, COSV100198569; called by muse, mutect2, varscan2
- VEPH1 | c.2470A>C p.R824= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV100747660; called by muse, mutect2
- VPS13C | c.7644A>G p.K2548= (on ENST00000644861 / NM_020821.3; = p.K2505= on NM_017684.5) | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99828802; called by muse, mutect2, varscan2
- XPO7 | c.2130C>T p.F710= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99381460; called by muse, mutect2, varscan2
- XRRA1 | c.918G>A p.E306= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1360170260, COSV100369912; called by muse, mutect2, varscan2
- ZNF813 | c.762G>A p.R254= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV101124883; called by muse, mutect2, varscan2
- DDX41 | c.*981G>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100394386; called by muse, mutect2, varscan2
- DDX41 | c.*980G>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100394357, COSV57254526; called by muse, mutect2, varscan2
- DUSP9 | c.*1G>A | 3'UTR (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100720123, COSV61438108; called by muse, mutect2
- KRT18P23 | chr22:44571483 G>T | 3'Flank (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- OR2W5 | n.1080A>G | RNA (SNP) | VAF 36/168 reads (21%) | called by muse, mutect2, varscan2
- PRDM15 | c.-383G>T | 5'UTR (SNP) | VAF 7/77 reads (9%) | catalogued as rs372704139, COSV54149860; called by muse, mutect2
- SHOX2 | c.*2G>C | 3'UTR (SNP) | VAF 34/344 reads (10%) | catalogued as COSV101273802; called by muse, mutect2, varscan2
- SSPOP | n.7803G>A | RNA (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100947524; called by muse, mutect2, varscan2
